Surgical pathology report (de-identified scan), TCGA case TCGA-97-A4LX, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-A4LX-01A (Primary Tumor).

[page 1 of 9]
ICD-0-3

adenocarcinoma, with mixed subtypes

8255/3

Site: lung, lingula C34.1

SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

fw
10/4/12

SPECIMENS:

1. F/S LINGULAR NODULE
2. F/S LEFT LOWER LOBE WEDGE
3. MARGIN OF LEFT LOWER LOBE WEDGE
4. LEVEL 5 LYMPH NODE, LEFT
5. LEVEL 7 LYMPH NODE, LEFT
6. LEVEL 9 LYMPH NODE, LEFT
7. BASILAR SEGMENT LEFT LOWER LOBE
- SEE ADDENDUM

Reason For Addendum #1: Molecular Studies

Reason For Addendum #2: Molecular Studies

DIAGNOSIS:

1. LUNG, LINGULA: WEDGE RESECTION

- ADENOCARCINOMA, SOLID PREDOMINANT (1 CM), SEE NOTE.
- THE STAPLE LINE MARGIN IS FREE OF TUMOR.

Note: The tumor consists of solid (60%), acinar (30%) and lepidic (10%) components. Immunohistochemical stains show that the tumor cells are positive for TTF-1 and Napsin-A while negative for p63, supporting the diagnosis.

2,3,7. LUNG, LEFT LOWER LOBE, BASILAR SEGMENT: WEDGE BIOPSIES AND COMPLETION SEGMENTECTOMY

- ADENOCARCINOMA, MICROPAPILLARY PREDOMINANT (3.5 CM), SEE NOTE.

[page 2 of 9]
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.
- FOUR LYMPH NODES, NEGATIVE FOR CARCINOMA (0/4).

Note: The tumor consists of micropapillary (60%), papillary (20%), lepidic (10%) and acinar (10%) components and measures 3.5 cm in aggregate dimension in Parts 2, 3 and 7. It is morphologically distinct from the concurrent lingular adenocarcinoma, favoring a separate primary. Results of mutational studies will be reported in addenda.

4. LYMPH NODE, LEFT LEVEL 5: BIOPSY

- FOUR LYMPH NODES, NEGATIVE FOR CARCINOMA (0/4).

5. LYMPH NODE, LEFT LEVEL 7: BIOPSY

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

6. LYMPH NODE, LEFT LEVEL 9: BIOPSY

- ONE LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1).

Specimens: 1: F/S LINGULAR NODULE

2: F/S LEFT LOWER LOBE WEDGE

3: MARGIN OF LEFT LOWER LOBE WEDGE

4: LEVEL 5 LYMPH NODE, LEFT

5: LEVEL 7 LYMPH NODE, LEFT

6: LEVEL 9 LYMPH NODE, LEFT

7: BASILAR SEGMENT LEFT LOWER LOBE

LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)

lingula and left lower

Procedure: Segmentectomy

Specimen Laterality: Left

Tumor Site: Lower lobe

Tumor Focality: Synchronous carcinomas (specify sites)

lingula and left lower lobe

TUMOR

Histologic Type: Adenocarcinoma, mixed subtype

Histologic Grade: G3: Poorly differentiated

EXTENT

Tumor Size: Greatest dimension (cm)

3.5cm

Visceral Pleura Invasion: Not identified

MARGINS

Bronchial Margin

Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by

[page 3 of 9]
invasive carcinoma

Vascular Margin: Uninvolved by invasive carcinoma

Parenchymal Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

STAGE (pTNM)

TNM Descriptors: m (multiple primary tumors)

Primary Tumor (pT):

pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura without bronchoscopic evidence of invasion more proximal than the lobar bronchus (i.e., not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung

Regional Lymph Nodes (pN)

pN0: No regional lymph node metastasis

Distant Metastases (pM): Not applicable

ADDITIONAL NON-TUMOR

Additional Pathologic Finding(s): Emphysema

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

M ex-smoker (120 pack-years) with a 1.6 cm RUL nodule, 3.7 cm LLL ground-glass mass and a 1 cm lingular nodule.

MACROSCOPIC DESCRIPTION:

The specimen is received in seven parts, each labeled with the patient's name.

1. Part one is received fresh, labeled 'lingular nodule'. It consists of a lingular segment of the lung measuring 15 x 7 x 3.5 cm. The staple line measures 17 cm which is shaved and the bronchial around inked blue. The pleura is gray pink and glistening and mottled moderately with fine black streaks. Also noted is a precut area on the pleura which reveals a sub pleural gray white firm nodule, measuring 1 x 0.9 x 0.8 cm located 2 cm from the staple line margin. The remainder of the bronchial is pink red blotchy and crepitant. No other nodule is grossly identified. Frozen section is performed on the nodule and resubmitted for permanent section. Representative section of the specimen and entire nodule are

[page 4 of 9]
submitted.

2. Part two is labeled 'left lower lobe wedge'. It consists of one piece of yellow-pink soft tissue measuring 2 x 1 x 0.5 cm. Entirely submitted in one cassette.

3. Part three is received fresh, labeled 'margin of left lower lobe wedge'. It consists of a stapled strip of light tan tissue measuring 3.5 x 0.4 x 0.3 cm. The staple line is shaved and the soft tissue is submitted.

4. Part four is labeled 'level #5 lymph node'. It consists of multiple soft red-black lymph nodes measuring 1.5 x 1.1 x 0.6 cm in aggregate. Entirely submitted in one cassette.

5. Part five is labeled 'level #7 lymph node'. It consists of a 1.5 x 1 x 0.8 cm red-black lymph node. Entirely submitted in one cassette.

6. Part six is labeled 'level #9 lymph node'. It consists of a 1.2 x 1 x 0.6 cm red-black lymph node. Entirely submitted in one cassette.

7. Part seven is received fresh, labeled 'basilar segment left lower lobe silk stitches on tumor location'. It consists of a segment of lung measuring 20 x 14 x 4.5 cm. The bronchial margin measures 1.5 cm and the vascular margin measures 1 cm. The pleura is gray pink glistening and mottled moderately with fine black streaks. There are two staple lines measuring 8 cm and 5 cm in length. There is a pre-cut area on the pleura which is marked with a stitch. At this area there is a grey tan firm mass, measuring 1.5 x 1 cm and located 1.5 cm from the bronchial resection margin, and 0.4 cm from the closest staple line which is shaved and the bronchial is inked black. The mass is located on the mediastinal surface of the lung. The remaining of the bronchial is pink red blotchy and crepitant. No other nodule is grossly identified. Representative sections of the specimen and the entire mass area with adjacent tissue are submitted.

SUMMARY OF SECTIONS:

1A frozen section of the nodule

1B-1D remaining of the nodule

[page 5 of 9]
1E random section of the lung parenchyma
1F staple line margin
2A in toto
3A soft tissue submitted, shaved
4A in toto
5A in toto
6A in toto
7A bronchial margin, shaved
7B vascular margin, shaved
7C-7H mass from stitch area with overlying pleura
7I-7L mass from stitch area after shaving the staple line
7M anthracotic lymph node from the hilum

SPECIAL PROCEDURES:

INTRA - OPERATIVE CONSULTATION:

1. Lung, lingula: wedge resection (Frozen Section)
- Adenocarcinoma with lepidic, acinar and solid patterns.

Result reported by

2. Lung, left lower lobe: wedge biopsy (Frozen Section)
- Adenocarcinoma with acinar and micropapillary patterns.

Result reported by

on

Intra-Operative Consultation #1 performed by

Intra-Operative Consultation #2 performed by

Final Diagnosis performed by

ADDENDUM 1:
Integrated Oncology

MOLECULAR ONCOLOGY
KRAS MUTATION ANALYSIS

[page 6 of 9]
Specimen #:

RESULTS: Positive for a p.G12A (c.34G>C) mutation in codon 12 of the KRAS gene.

INTERPRETATION: Mutations in the KRAS gene are reported to correlate with poor prognosis and resistance to tyrosine kinase inhibitor therapies in patients with non-small lung cancer.

COMMENT:

KRAS mutations occur in 15-30% of non-small-cell lung cancer (NSCLC) patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected.

This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

NSCLC

Mascaux C, Iannino N, et al. British Journal of Cancer, 2005; 92:11-139

Pao W, Wang TY, et al. PLoS Medicine, 2005; 2(1):57-61

[page 7 of 9]
Eberhard DA, Johnson BE, et al. J Clin Oncol, 2005; 23:5900-5909
Han SW, Kim TY, et al. Clin Cancer Res. 2006; 12(8):2538-2544
CRC
DiFiore C, Blanchard F, et al. Br J Cancer, 2007; 96:1166-1169
Lievre A, Bachet J-B, et al. Cancer Res, 2006; 66:3992-3995,

This test was developed and its performance characteristics determined by _____ The laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be only used in the context of other diagnostic tests or clinical work-up related to treatment decisions.

Electronically signed by:
Date

Addendum #1 performed by

ADDENDUM 2:

EGFR Mutation Analysis

Specimen #:

Clinical Data: Adenocarcinoma.

RESULTS: No mutation detected.

INTERPRETATION: No mutations were identified; in the sample provided for analysis. Fewer than 5% of non-small-cell lung carcinoma patients without identifiable mutations are reported to be responsive to EGFR tyrosine kinase inhibitor therapies.

[page 8 of 9]
COMMENT: Forty percent (40%) or more cellularity is optimal for this mutation analysis. The sample submitted showed 50% tumor cellularity upon pathologist review.

A frequently occurring sequence change 2361G>A (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine kinase domain of the epidermal growth factor receptor gene are reported to be associated with differential response to EGFR tyrosine kinase inhibitors. The objective response rate among patients with EGFR mutation ranges from 55 to 82%.

Exons 18-21 of the EGFR tyrosine kinase domain; mutations in these exons, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample from this tumor.

This test is not validated for non-small cell lung carcinoma. The clinical significance of this test in other tumor types is unknown.

METHOD:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the samples, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

1. Azzoli CG, et al. J Clin Oncol. 2009; 27:6251-6266
2. Jackman DM et al. Clin Carcinoma Res 2009; 15:5267-5273
3. Mok TS, et al. N Engl J Med. 2009;361:947-957
4. Sharma SV, et al. Nat Rev Carcinoma. 2007;169-181

DISCLAIMER:

This test was developed and its performance characteristics

[page 9 of 9]
determined by The laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be only used in the context of other diagnostic tests or clinical work-up related to treatment decisions.

Electronically signed by:
Date:

Addendum #2 performed by

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.
The tests were developed and their performance characteristics determined by

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Primary/Referral Site Discrepancy		
Equal/Synchronous/Primary Noted		

Source: NCI Genomic Data Commons file 795b87f3-6756-47c9-bc2a-b1c9e1b041d8 (TCGA-97-A4LX.1D7E3689-7B7F-4916-BCD9-04C5A98F09DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).